Somatic mutation profile of tumor specimen CUPP-B38Q-TTM1-A (aliquot CUPP-B38Q-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38Q, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 78.7 years (28,740 days).
Specimen CUPP-B38Q-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7879bc3e-b286-44fa-b2d4-ad7b19847b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38Q-NB1-A (Blood Derived Normal), aliquot CUPP-B38Q-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60aab956-6720-4b93-a16a-0a833153a8d5

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.16504C>T p.R5502W | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as rs377580543; called by muse, varscan2
- AMDHD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs757892525; called by mutect2, varscan2
- ANPEP | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746814863, COSV55595155; called by mutect2, varscan2
- CD1D | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV63810023; called by muse, mutect2, varscan2
- CDH2 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs17853633, COSV99296530; called by mutect2, varscan2
- CHRM3 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.267); catalogued as COSV55086106; called by muse, mutect2, varscan2
- CTSH | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs1438048250, COSV99585501; called by muse, mutect2, varscan2
- DIS3L2 | c.1648del p.R550Vfs*5 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | catalogued as COSV56054679; called by mutect2, pindel, varscan2
- FBN3 | c.4880A>G p.N1627S | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs762585165; called by muse, mutect2, varscan2
- FOLH1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV57054518; called by muse, mutect2, varscan2
- GPRASP2 | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 177/456 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.382); catalogued as rs747041179; called by muse, mutect2, varscan2
- KCNH4 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1057461290, COSV52916572; called by muse, mutect2, varscan2
- MMRN1 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369300887, COSV53341539; called by muse, mutect2, varscan2
- OR11H12 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs758660271; called by mutect2, varscan2
- PCDHA2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs782594473, COSV65366061; called by mutect2, varscan2
- PDHX | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1291802569, COSV53506842; called by muse, mutect2, varscan2
- PDPR | c.662A>C p.Q221P | Missense Mutation (SNP) | VAF 84/656 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs746584856; called by muse, mutect2, varscan2
- TNR | c.688T>G p.C230G | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99690996; called by mutect2, varscan2
- ZFHX4 | c.3880A>G p.M1294V | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs781208653, COSV51459007; called by mutect2, varscan2
- ZFR | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1440676053; called by muse, mutect2, varscan2
- ALPK2 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | called by mutect2, varscan2
- CFAP54 | c.8986A>T p.N2996Y | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by mutect2, varscan2
- CSNK1E | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.025); called by mutect2, varscan2
- DHRS7C | c.791G>T p.R264L (on ENST00000330255 / NM_001220493.2; = p.R263L on NM_001105571.3) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DLX1 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KMT2C | c.6839G>A p.G2280E | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by mutect2, varscan2
- KNL1 | c.3474C>A p.H1158Q (on ENST00000346991 / NM_170589.5; = p.H1132Q on NM_144508.5) | Missense Mutation (SNP) | VAF 158/446 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MRC2 | c.2119C>G p.L707V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MTIF2 | c.1626C>G p.H542Q | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by mutect2, varscan2
- MUC5B | c.10984del p.R3662Vfs*35 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- PBRM1 | c.835dup p.I279Nfs*8 | Frame Shift Ins (INS) | VAF 122/231 reads (53%) | called by mutect2, varscan2
- PCDH10 | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.028); called by muse, varscan2
- PHF21B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.223); called by mutect2, varscan2
- PITPNM1 | c.2784_2785del p.C928* | Nonsense Mutation (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- SPEM3 | c.3067C>A p.P1023T | Missense Mutation (SNP) | VAF 121/348 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SRPK1 | c.1623del p.F542Lfs*27 | Frame Shift Del (DEL) | VAF 71/294 reads (24%) | called by pindel, varscan2
- TMEM120A | c.356C>G p.T119R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- TMEM178B | c.20_21dup p.L8Cfs*8 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- TMEM268 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 51/166 reads (31%) | called by muse, mutect2, varscan2
- VPS41 | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AATK | c.2892G>A p.A964= (on ENST00000326724 / NM_001080395.3; = p.A861= on NM_004920.2) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs374078937; called by mutect2, varscan2
- ABLIM2 | c.744C>T p.G248= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs781450672; called by mutect2, varscan2
- ADHFE1 | c.1035A>G p.A345= | Silent (SNP) | VAF 92/322 reads (29%) | called by muse, mutect2, varscan2
- AVPR2 | c.474G>T p.R158= | Silent (SNP) | VAF 17/58 reads (29%) | called by mutect2, varscan2
- CERS1 | c.498G>A p.T166= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs777172267, COSV55930860; ClinVar: likely benign; called by mutect2, varscan2
- GTF3C1 | c.111G>T p.L37= | Silent (SNP) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- HEATR1 | c.5529G>A p.P1843= | Silent (SNP) | VAF 97/346 reads (28%) | catalogued as rs372759005; called by muse, mutect2, varscan2
- KCNB1 | c.2082T>C p.P694= | Silent (SNP) | VAF 63/170 reads (37%) | called by muse, mutect2, varscan2
- MAGEA9B | c.912T>C p.Y304= | Silent (SNP) | VAF 14/45 reads (31%) | called by mutect2, varscan2
- PCDHA2 | c.1701G>T p.A567= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV65366104; called by mutect2, varscan2
- RBM20 | c.660G>A p.G220= | Silent (SNP) | VAF 42/134 reads (31%) | called by mutect2, varscan2
- ZFHX4 | c.1356C>T p.N452= | Silent (SNP) | VAF 134/461 reads (29%) | catalogued as rs368840810, COSV51456170; called by muse, mutect2, varscan2
- AL354685.1 | n.891G>A | RNA (SNP) | VAF 88/346 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.34354+375C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs913411241; called by mutect2, varscan2
